Somatic mutation profile of tumor specimen MP2PRT-PATZBG-TMP1-A (aliquot MP2PRT-PATZBG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATZBG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,298 days).
Specimen MP2PRT-PATZBG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d41b161-a4b0-492f-b2da-079e002456d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZBG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZBG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e4462fb-02cf-41ff-9056-5a1135306c79

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 51/353 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.4423G>A p.G1475R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.226); catalogued as rs796053216, COSV61993169; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- FRMD4A | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 127/535 reads (24%) | catalogued as rs748209997; called by muse, mutect2, varscan2
- GOLGA5 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs142072754, COSV99031449; called by muse, mutect2, varscan2
- NADK | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 66/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58271822; called by muse, varscan2
- NDUFA7 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 191/429 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1001956315; called by muse, mutect2, varscan2
- OR10A2 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 191/439 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs756341258; called by muse, mutect2, varscan2
- PCDH18 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 62/508 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766678974, COSV100787360, COSV61266240; called by muse, varscan2
- PNLIPRP1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs369604475, COSV100724405; called by muse, mutect2
- PSD | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 66/1066 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs771665440, COSV99192889; called by muse, mutect2
- TBC1D30 | c.1852C>T p.R618* (on ENST00000542120; = p.R455* on NM_015279.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/354 reads (11%) | catalogued as rs1330542816, COSV57486095; called by muse, mutect2, varscan2
- TMIE | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 75/434 reads (17%) | catalogued as rs770351795; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- CEP152 | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FLT3 | c.2523_2524insGAGCCC p.N841_Y842insEP | In Frame Ins (INS) | VAF 36/214 reads (17%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 84/1016 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2
- ABCA6 | c.1389T>C p.D463= | Silent (SNP) | VAF 78/234 reads (33%) | catalogued as rs777448220; called by muse, mutect2, varscan2
- FOXN4 | c.1416C>T p.S472= | Silent (SNP) | VAF 101/502 reads (20%) | catalogued as rs764575314, COSV54495491; called by muse, mutect2, varscan2
- GALNT12 | c.603C>T p.R201= | Silent (SNP) | VAF 177/405 reads (44%) | catalogued as rs1202870372, COSV66663766; called by muse, mutect2, varscan2
- NIPBL | c.6151C>T p.L2051= | Silent (SNP) | VAF 75/184 reads (41%) | called by muse, mutect2, varscan2
- SCAF1 | c.1008G>A p.P336= | Silent (SNP) | VAF 15/546 reads (3%) | catalogued as rs888560439; called by muse, mutect2
- TRIM40 | c.588C>T p.S196= (on ENST00000376724; = p.S167= on NM_138700.4) | Silent (SNP) | VAF 94/1006 reads (9%) | called by muse, mutect2
- ZNF579 | c.927C>T p.L309= | Silent (SNP) | VAF 20/634 reads (3%) | catalogued as rs1013246423; called by muse, mutect2
